CCDI case PBBSRE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites within respiratory system and intrathoracic organs.
https://portal.gdc.cancer.gov/cases/fbcd99fc-60e7-48e2-b1ee-41f6fea77763

Demographics
Sex at birth: female.

Diagnoses (1)
1. Malignant tumor, spindle cell type: ICD-O-3 morphology code: 8004/3; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 10.6 years (3,879 days).

Biospecimens (3 samples)
- Sample 0DFWCC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFWCD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DFWCE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
